Gene-level copy-number profile of tumor specimen ALCH-B4UQ-TTP1-A from ALCHEMIST case ALCH-B4UQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.3 years (20,919 days).
Specimen ALCH-B4UQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b2ec7510-cc13-4b6f-9365-0c9da3bc91a4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4UQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,251 have no estimate.
https://portal.gdc.cancer.gov/files/cf4c4196-e367-4fc8-a216-c9d723403f5a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 86; copy number 1: 14,712; copy number 2: 33,469; copy number 3: 6,981; copy number 4: 2,143; copy number 5: 954; copy number 6: 19; copy number 7: 3; copy number 8: 2; copy number 34: 1; copy number 37: 2.

Homozygous deletions (total copy number 0; autosomes only): 84 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:113,211,421–113,278,921, 2 genes: PAX8-AS1, PAX8.
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr4:49,486,926–49,523,857, 4 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr8:11,576,257–12,704,056, 57 genes: LINC00208, GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1, CTSB, AC025857.1, OR7E158P, OR7E161P, DEFB136, DEFB135, DEFB134, AC107918.3, DEFB131E, AC107918.2, AC107918.1, DEFB131C, DEFB130B, RNA5SP253, DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P, ALG1L11P, FAM86B1, AC145124.1, ENPP7P12, DEFB131D, DEFB130A, RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3, FAM90A25P, ALG1L12P, FAM86B2, ENPP7P6, AC068587.4, AC130352.1, RPS3AP34, AC068587.2, RPS3AP35, AC068587.3, AC068587.1, OR7E8P, OR7E15P, OR7E10P.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr8:43,539,137–43,674,591, 5 genes: AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr9:124,853,417–124,877,733, 3 genes: WDR38, RPL35, ARPC5L.
- chr9:124,887,410–124,887,549, 1 gene (within-gene range 0–1): RNU4-82P.
- chr12:53,935,328–53,963,697, 4 genes (within-gene range 0–2): HOXC13-AS, HOXC13, HOXC12, AC012531.5.
- chr18:14,946,267–14,993,235, 4 genes: LINC01443, LINC01444, AP005121.2, AP005242.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 981 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:25,547,762–32,428,131, 149 genes, copy number 5 (broad region; genes not listed).
- chr7:33,725,981–45,768,985, 224 genes, copy number 5–6 (broad region; genes not listed).
- chr7:45,990,905–62,275,678, 225 genes, copy number 5 (broad region; genes not listed).
- chr7:63,113,635–63,510,165, 31 genes, copy number 5: SAPCD2P4, SEPTIN14P1, AC069285.1, AC092001.1, PHKG1P1, AC006455.8, SEPTIN7P4, AC006455.7, ZNF733P, AC006455.1, ARAFP3, AC006455.6, AC006455.5, AC006455.2, AC006455.3, AC006455.4, VN1R31P, VN1R32P, AC073188.3, AC073188.4, AC073188.2, AC073188.1, AC073188.5, AC073188.6, SLC25A1P2, VN1R33P, ARAFP2, ZNF734P, AC006457.1, SEPTIN7P5, PHKG1P2.
- chr11:64,987,945–65,570,423, 56 genes, copy number 5: BATF2, ARL2, ARL2-SNX15, MIR6879, AP000436.1, SNX15, SAC3D1, NAALADL1, CDCA5, ZFPL1, TMEM262, VPS51, AP003068.1, TM7SF2, ZNHIT2, AP003068.3, AP003068.4, FAU, SYVN1, MRPL49, MIR6751, HIGD1AP10, RNU2-23P, PDCL2P2, SPDYC, PGAM1P8, AP003068.2, CAPN1, SLC22A20P, POLA2, AP000944.5, AP000944.7, CDC42EP2, DPF2, TIGD3, AP000944.1, SLC25A45, FRMD8, NEAT1, AP000944.4, AP000944.3, AP000944.2, MIR612, AP000769.4, AP000769.1, LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3, SNRPGP19, SCYL1, LTBP3, AP001362.1, ZNRD2-AS1.
- chr11:66,070,272–67,805,336, 107 genes, copy number 5 (broad region; genes not listed).
- chr15:21,293,653–21,325,241, 3 genes, copy number 7 (within-gene range 4–7): AC068446.1, AC068446.2, RNU6-1235P.
- chr17:14,767,583–16,437,003, 67 genes, copy number 5 (broad region; genes not listed).
- chr20:19,212,642–19,722,926, 1 gene, copy number 5 (within-gene range 3–5): SLC24A3.
- chr20:19,693,209–23,776,169, 99 genes, copy number 5 (broad region; genes not listed).
- chr20:53,875,252–55,684,915, 13 genes, copy number 5: SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1.
- chr22:21,125,660–21,128,063, 1 gene, copy number 5: POM121L7P.
- chr22:21,300,990–21,371,945, 5 genes, copy number 8–37 (within-gene range 4–37): FAM230H, AP000552.2, PPP1R26P5, LINC01651, AP000552.1.

Autosomal genes at a single copy (total copy number 1): 14,712. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
